Somatic mutation profile of tumor specimen TCGA-J8-A3YG-01A (aliquot TCGA-J8-A3YG-01A-11D-A22Z-08) from TCGA case TCGA-J8-A3YG, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 54.2 years (19,785 days).
Specimen TCGA-J8-A3YG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b917273-07a2-4740-bc61-4fb7537c57df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3YG-10A (Blood Derived Normal), aliquot TCGA-J8-A3YG-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78fdf2ee-2d3d-4241-9969-aeeb2b2cfce8

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Del 1, 5'Flank 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CELSR1 | c.8863G>T p.A2955S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.049); catalogued as COSV53091128, COSV99420507; called by muse, mutect2, varscan2
- PLXND1 | c.3724G>T p.A1242S | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs140631068, COSV100140549; called by muse, mutect2
- SACM1L | c.1682T>C p.I561T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101203812; called by muse, mutect2, varscan2
- SWSAP1 | c.91G>C p.G31R (on ENST00000312423; = p.G52R on NM_175871.4) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV99710346; called by muse, mutect2, varscan2
- ADAM2 | c.1523del p.P508Lfs*20 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- TRARG1 | c.120C>G p.T40= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100416993; called by muse, mutect2, varscan2
- DEFB119 | c.61+1286C>T | Intron (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59267193; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80559141 C>T | 5'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
